TCGA case TCGA-A6-6648 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/65056295-8fcd-4f82-a3c9-a5acd79521fe

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.6; Tissue or organ of origin: Descending colon; Site of resection or biopsy: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 56.5 years (20,641 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IVA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 766 days (2.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 21; Lymphatic invasion present: No; Non nodal tumor deposits: No; Vascular invasion present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cetuximab; Initial disease status: Progressive Disease; Days to treatment start: 63 days; Days to treatment end: 77 days; Number of cycles: 1; Prescribed dose: 1050; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 63 days; Days to treatment end: 93 days; Number of cycles: 1; Treatment dose: 18,900 mg; Prescribed dose: 6300; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 63 days; Days to treatment end: 91 days; Number of cycles: 1; Treatment dose: 2,540 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Oxaliplatin; Initial disease status: Progressive Disease; Days to treatment start: 63 days; Days to treatment end: 91 days; Number of cycles: 1; Treatment dose: 540 mg; Prescribed dose: 180; Prescribed dose units: mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 58.4 years (21,327 days); Days to diagnosis: 686 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (4 entries)
- Days to follow up: 253 days; Disease response: Tumor Free.
- Days to follow up: 344 days; Disease response: Tumor Free.
- Day 686 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 686 days (1.9 years).
- Days to follow up: 766 days (2.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 2.5 ng/mL.
- KRAS mutation, nos: Negative.
- MLH1 (IHC): Normal.
- MSH2 (IHC): Normal.
- MSH6 (IHC): Normal.
- PMS2 (IHC): Normal.
- Microsatellite Instability: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 87 kg; Height: 182.8 cm; BMI: 26.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-6648-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.9; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-A6-6648-01A-01-BS1: Section location: Bottom; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 30; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 10.
  Slide TCGA-A6-6648-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 7.
- Sample TCGA-A6-6648-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-6648-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 2.5; Lymphovascular invasion indicator: No; Microsatellite instability: No; Loci tested count: 5; Loci abnormal count: 0; KRAS gene analysis indicator: Yes; KRAS mutation found: No; BRAF gene analysis indicator: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: Yes.
- Loss expression of mismatch repair proteins by ihc results: Mismatch rep proteins loss IHC: MLH1-Expressed; Mismatch rep proteins loss IHC: MSH2-Expressed; Mismatch rep proteins loss IHC: PMS2-Expressed; Mismatch rep proteins loss IHC: MSH6-Expressed.
- Drug treatment 1: Regimen number: 1; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Metastatic.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Cetuximab Study drug; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Metastatic.
- Drug treatment 4: Regimen number: 1; Pharmaceutical therapy drug name: 5 FU; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Metastatic.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 766 days; disease-specific survival: no event (censored), 766 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 686 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-6648-01A-11D-1770-01): tumor purity 0.46, ploidy 3.18, whole-genome doublings 1.
